Somatic mutation profile of tumor specimen TCGA-YL-A8SB-01A (aliquot TCGA-YL-A8SB-01A-31D-A377-08) from TCGA case TCGA-YL-A8SB, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.9 years (22,991 days).
Specimen TCGA-YL-A8SB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c53491-cb6f-424d-af8f-0b079fe7686c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SB-10A (Blood Derived Normal), aliquot TCGA-YL-A8SB-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9471e00-b93a-42a3-8e2f-533daccc8abf

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BMP5 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV100896129, COSV100896256; called by muse, mutect2, varscan2
- CDH13 | c.1058T>A p.I353N | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99229629; called by muse, mutect2, varscan2
- CFLAR | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100009774; called by muse, mutect2, varscan2
- DICER1 | c.5095G>A p.D1699N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100602441, COSV100602545; called by muse, mutect2, varscan2
- GDPD4 | c.559T>G p.C187G | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100265567; called by muse, mutect2, varscan2
- HIC2 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs745373955, COSV68041808; called by muse, mutect2, varscan2
- IGFBP6 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV100037259; called by muse, mutect2, varscan2
- KCNC4 | c.1871G>T p.C624F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100873680; called by muse, mutect2
- KCNK2 | c.496C>T p.R166C (on ENST00000444842 / NM_001017425.3; = p.R151C on NM_014217.4) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs576428312, COSV67203905; called by muse, mutect2, varscan2
- MYO1E | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99896422; called by muse, mutect2, varscan2
- NPY2R | c.827T>A p.V276E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279863; called by muse, mutect2, varscan2
- PFKFB4 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 29/137 reads (21%) | PolyPhen benign (0.337); catalogued as COSV99219956; called by muse, mutect2, varscan2
- POLR2B | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100108301; called by muse, mutect2, varscan2
- PPIF | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.981); catalogued as COSV99830963; called by muse, mutect2, varscan2
- RNF215 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs767824470, COSV99306682; called by muse, mutect2, varscan2
- SMC2 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99659509; called by muse, mutect2, varscan2
- UGT2B15 | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100592427; called by muse, mutect2
- ZNF696 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as rs1166917881, COSV100350622; called by muse, mutect2
- ERF | c.27del p.F9Lfs*68 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- KMT2D | c.6731del p.F2244Sfs*20 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- SLC1A6 | c.107_108del p.R36Hfs*140 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by pindel, varscan2
- DNAH8 | c.8958G>T p.L2986= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100546764, COSV100546838, COSV59425223; called by muse, mutect2
- KLHDC7A | c.1827G>C p.L609= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101272839; called by muse, mutect2
- TTC39C | c.1332G>T p.A444= (on ENST00000317571 / NM_001135993.2; = p.A383= on NM_153211.4) | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs762929866, COSV100455556, COSV58215855; called by muse, mutect2, varscan2
- ZNF454 | c.1149T>G p.P383= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100195295; called by muse, mutect2, varscan2
